Surgical pathology report (de-identified scan), TCGA case TCGA-TT-A6YO, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University of Pennsylvania, specimen TCGA-TT-A6YO-01A (Primary Tumor).

[page 1 of 2]
Print Date.....

Date Collected

Date Received

Accession No. [Redacted]

Physician

Copy to:

Sex: Female

Surgical Pathology Report

Accession Number	Collection Date/Time	Received Date/Time	Verified Date/Time	Pathologist
------------------	----------------------	--------------------	--------------------	-------------

Clinical Information

year old woman with history of hypertension and two left adrenal masses
Pre-Operative Diagnosis: Not specified
Post-Operative Diagnosis: Not specified
Operation: Laparoscopic left adrenalectomy for pheochromocytoma
Specific questions to be answered: None

Specimen:

1 Left Adrenal

Final Diagnosis

1. Left adrenal, 41.2 g, laparoscopic left adrenalectomy:
- Pheochromocytoma, 2.2 cm, completely excised; see note.
- Adrenal cortical adenoma, 2.0 cm, completely excised.

The case material was reviewed and the report verified by:

(Electronic signature)

Verification Date.

Note

The PASS score for this lesion is 10/20. There is focal necrosis (2), high cellularity (2), tumor cell spindling (2), focally 3 mitoses/10 hpf (2), profound nuclear pleomorphism (1) and nuclear hyperchromasia (1). Large tumor nests/diffuse growth, cellular monotony, atypical mitoses, tumor extension into the adipose tissue, vascular invasion and capsular invasion are not observed.

Immunohistochemical stains for synaptophysin, chromogranin, S100, ki-67 and SDHB were performed with appropriate controls on block 11 (see IHC disclaimer). The tumor cells are positive for synaptophysin, chromogranin, and focally positive for S100 (sustentacular pattern). Ki-67 staining shows a low proliferation index. This supports the diagnosis of pheochromocytoma above.

Immunostain for SDHB was performed on block 11 for screening possible SDHB germline mutation with adequate controls. Additional molecular/genetic test is recommended for a patient with a tumor showing negative or weak cytoplasmic SDHB staining pattern, if clinically indicated. The tumor shows moderate cytoplasmic SDHB staining (60%).

Disclaimer:

N/A

Name
MRN

[page 2 of 2]
Print Date:
Date Collected
Date Received
Accession No
Physician
Copy to:

Sex: Female

Surgical Pathology Report

Accession Number	Collection Date/Time	Received Date/Time	Verified Date/Time	Pathologist
------------------	----------------------	--------------------	--------------------	-------------

The above in-vitro IHC tests may have used reagents labeled for IVD (In Vitro Diagnostic Use), IUO (Investigational Use Only) and/or RUO (Research Use Only) and have not been cleared or approved by the U.S Food and Drug Administration. However, the FDA has determined that such clearance or approval is not necessary for ASR class I tests intended to provide pathologists with adjunctive information to assist their morphologic evaluation. The tests using IUO or IUO reagents were developed and their performance characteristics were validated for diagnostic use by the Laboratory of Immunohistochemistry, Anatomic Pathology at the . This laboratory is regulated under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical tests. These Class I ASR tests are not intended to provide diagnostic, prognostic, predictive or therapeutic information that is not directly confirmed by routine histopathologic internal or external control specimens.

Gross Description

The case is received in one formalin filled container, labeled with the patient's name and medical record number.

Specimen 1 is designated left adrenal. The specimen weighs 41.2 g and overall measures 8.6 x 5.4 x 1.6 cm. The external surface is inked black. The specimen is serially incised to reveal two well-circumscribed masses. One mass has a yellow cut surface and measures 2.0 x 1.8 x 1.6 cm. The other mass has a red-brown cut surface and measures 2.2 x 1.9 x 1.5 cm. Neither mass has areas of obvious hemorrhage or necrosis. The yellow mass appears to arise from the adrenal cortex, while the red-brown mass appears to arise from the medulla. The yellow mass is entirely submitted in 1A through 1D. The red-brown mass is entirely submitted in 1E through 1J. No other masses or lesions are identified. Representative sections of unremarkable adrenal gland are submitted in 1K and 1L.

SUMMARY OF SECTIONS: 12, multiple, representative

Dictated by

Pathologist(s)

N/A

Name:
MRN:

Source: NCI Genomic Data Commons file ef0fd1a4-12cc-4e4b-9f1d-327ef3a1a2b7 (TCGA-TT-A6YO.EBFBC36F-D75E-4E62-8DAB-BBE5890DEB34.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).